Somatic mutation profile of tumor specimen 0DW72Y from CCDI case PBCNLW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Meningothelial meningioma; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 9.2 years (3,346 days).
Specimen 0DW72Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be42833f-219f-4203-9fa3-20aabb4a4518.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW72O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/776842f5-98ec-462c-af67-304ee848ea3b

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 3, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPEG | c.3051G>A p.M1017I | Missense Mutation (SNP) | VAF 82/870 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1367891670, COSV56672855; called by muse, mutect2
- TYRO3 | c.2066G>T p.G689V | Missense Mutation (SNP) | VAF 324/997 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99778164; called by muse, mutect2, varscan2
- ARHGAP30 | c.2545C>T p.Q849* | Nonsense Mutation (SNP) | VAF 53/677 reads (8%) | called by muse, mutect2
- PRAMEF7 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 116/1653 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2
- DMRT3 | c.1284C>T p.R428= | Silent (SNP) | VAF 102/996 reads (10%) | catalogued as rs764166688, COSV51902493; called by muse, mutect2
- FECH | c.333C>T p.I111= | Silent (SNP) | VAF 172/2054 reads (8%) | catalogued as rs761513962; called by muse, mutect2
- FH | c.684C>A p.I228= | Silent (SNP) | VAF 46/1950 reads (2%) | called by muse, mutect2
- ZNF608 | c.-18A>G | 5'UTR (SNP) | VAF 25/516 reads (5%) | called by muse, mutect2
